Somatic mutation profile of tumor specimen TCGA-D1-A0ZP-01A (aliquot TCGA-D1-A0ZP-01A-21D-A10M-09) from TCGA case TCGA-D1-A0ZP, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 59.1 years (21,581 days).
Specimen TCGA-D1-A0ZP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7019c3d1-a433-43bd-b491-31997860c631.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A0ZP-10A (Blood Derived Normal), aliquot TCGA-D1-A0ZP-10A-01D-A10M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ceca507-1f9d-404e-b0c6-1a5fa2d50c99

The open-access MAF lists 31 somatic variants for this specimen: 23 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 21, Silent 8, In Frame Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 15/37 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.2431C>T p.R811C | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.19); catalogued as rs758777521, CM1414491, COSV64671374, COSV64672440; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD4 | c.3704A>C p.H1235P (on ENST00000357008 / NM_001363606.2; = p.H1248P on NM_001273.5) | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58912475; called by muse, mutect2, varscan2
- COBL | c.3139G>A p.G1047S | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746769073, COSV54360791; called by muse, mutect2, varscan2
- DICER1 | c.5107C>T p.R1703C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs878855272, COSV58624724, COSV58624882; ClinVar: uncertain significance; called by muse, mutect2
- FAN1 | c.289G>A p.V97I | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs375827355, COSV62952415; called by muse, mutect2, varscan2
- FAT2 | c.5357T>A p.V1786E | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55831346; called by muse, mutect2, varscan2
- GIMAP6 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.665); catalogued as COSV61035093; called by muse, mutect2, varscan2
- GNA13 | c.1084G>A p.V362M | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71475342; called by muse, mutect2, varscan2
- H2AC15 | c.337C>G p.Q113E | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.129); catalogued as COSV57586735; called by muse, mutect2, varscan2
- INSC | c.264C>G p.C88W | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV65411656, COSV65413611; called by muse, mutect2, varscan2
- LMLN | c.440C>A p.A147E | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated (0.86); PolyPhen benign (0.038); catalogued as COSV57605605; called by muse, mutect2, varscan2
- LPL | c.921G>T p.K307N | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV60931016; called by muse, mutect2, varscan2
- LRTM2 | c.142C>G p.R48G | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV54566979; called by muse, mutect2, varscan2
- LTA | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.702); catalogued as rs377059622; called by muse, mutect2, varscan2
- OR2C3 | c.34G>T p.V12F | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.088); catalogued as COSV63576601; called by muse, mutect2, varscan2
- OR5AC2 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.036); catalogued as rs755877682, COSV62279133; called by muse, mutect2, varscan2
- PAQR5 | c.572A>G p.Y191C | Missense Mutation (SNP) | VAF 90/198 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV61819434; called by muse, mutect2, varscan2
- RYR2 | c.5755C>T p.R1919W | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs771469528, COSV100767322, COSV63676519; ClinVar: uncertain significance; called by muse, varscan2
- ZFYVE9 | c.3577C>G p.Q1193E | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as COSV55101497; called by muse, mutect2, varscan2
- SCRN2 | c.913_915dup p.L305dup | In Frame Ins (INS) | VAF 17/42 reads (40%) | called by mutect2, pindel, varscan2
- SRPRA | c.1061_1063del p.V354del | In Frame Del (DEL) | VAF 37/111 reads (33%) | called by mutect2, pindel, varscan2
- DNAI1 | c.1881C>A p.A627= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as COSV54285475; called by muse, mutect2, varscan2
- DNAI2 | c.24C>G p.V8= | Silent (SNP) | VAF 19/32 reads (59%) | catalogued as COSV56763087; called by muse, mutect2, varscan2
- FOXI1 | c.567C>T p.D189= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as COSV60390372; called by muse, mutect2, varscan2
- IBTK | c.138T>C p.T46= | Silent (SNP) | VAF 39/149 reads (26%) | catalogued as COSV60396730; called by muse, mutect2, varscan2
- IPO4 | c.1539C>G p.A513= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV55782416; called by muse, mutect2, varscan2
- NOBOX | c.429G>A p.P143= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as rs748148557, COSV56192840; called by muse, mutect2, varscan2
- OR2L8 | c.717C>T p.T239= | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as rs1365112377, COSV61728714; called by muse, mutect2
- RAI2 | c.318G>A p.P106= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs1332551757, COSV58966571; called by muse, mutect2, varscan2
